PECGS case C030-004507 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/f6c3572c-19ad-4fc9-9140-e75872102335

Demographics
Sex at birth: male; Age at index: 45 years; Year of birth: 1975.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Sigmoid colon; Age at diagnosis: 45.2 years (16,509 days); AJCC clinical stage: Stage IV; AJCC pathologic stage: Stage IV.

Biospecimens (2 samples)
- Sample C030-004507_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C030-004507_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
